Somatic mutation profile of tumor specimen 0DS0ZZ from CCDI case PBCHLH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,700 days).
Specimen 0DS0ZZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49d51cd6-0734-4da2-b657-aeaccfbbdb4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0ZE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/375df45a-c431-4c3a-a637-a662205e7c20

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H1-3 | c.222A>G p.V74= | Silent (SNP) | VAF 262/847 reads (31%) | catalogued as rs776944538; called by muse, varscan2
- NEGR1 | c.414T>C p.P138= | Silent (SNP) | VAF 228/918 reads (25%) | called by muse, varscan2
